Gene-level copy-number profile of tumor specimen TCGA-59-2355-01A from TCGA case TCGA-59-2355, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3.
Specimen TCGA-59-2355-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f3bf0766-203a-4cef-9b0f-d9e84bfcfb38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-59-2355-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff47c8ac-7ddc-4af8-9bc1-0c37886390ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,450; copy number 2: 32,491; copy number 3: 7,524; copy number 4: 1,060; copy number 5: 254; copy number 6: 6; copy number 8: 24; copy number 12: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-59-2355-01A-01D-0704-01): tumor purity 0.79, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 290 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,513,999–43,389,808, 284 genes, copy number 5–12 (within-gene range 1–12) (broad region; genes not listed).
- chr8:41,032,892–41,309,473, 6 genes, copy number 6 (within-gene range 3–6): RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.

Autosomal genes at a single copy (total copy number 1): 16,029. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
